Somatic mutation profile of tumor specimen MP2PRT-PARJZV-TMP1-A (aliquot MP2PRT-PARJZV-TMP1-A-1-0-D-A82K-36) from MP2PRT case MP2PRT-PARJZV, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Blood; Age at diagnosis: 2.2 years (799 days).
Specimen MP2PRT-PARJZV-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 538941aa-cddd-4525-8926-ee281d736f1d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PARJZV-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PARJZV-NB1-A-1-0-D-A82K-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f905d368-ca02-4ab1-90f1-68de56f963c1

The open-access MAF lists 3 somatic variants for this specimen: 3 protein-altering or splice-affecting.
By variant classification: Missense Mutation 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GATA3 | c.823C>T p.R275W | Missense Mutation (SNP) | VAF 17/616 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60518027; called by muse, mutect2
- EIF4E2 | c.182C>T p.T61I | Missense Mutation (SNP) | VAF 54/497 reads (11%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- PRSS16 | c.1196C>A p.A399E | Missense Mutation (SNP) | VAF 130/435 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.147); called by muse, mutect2, varscan2
